Somatic mutation profile of tumor specimen TCGA-HC-A76X-01A (aliquot TCGA-HC-A76X-01A-11D-A33T-08) from TCGA case TCGA-HC-A76X, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.3 years (22,756 days).
Specimen TCGA-HC-A76X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88e9ef57-f7b6-47bd-b359-a3652dabbe76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-A76X-10A (Blood Derived Normal), aliquot TCGA-HC-A76X-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d9183ba-5248-4a31-9b30-7b246d037aac

The open-access MAF lists 29 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 21, Silent 5, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BASP1 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as rs1395951896, COSV59469459; called by muse, mutect2, varscan2
- BDP1 | c.7435G>T p.A2479S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as COSV100703367; called by muse, mutect2
- CPSF7 | c.1339C>T p.R447W (on ENST00000394888 / NM_001136040.4; = p.R490W on NM_024811.4) | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV61211952; called by muse, mutect2, varscan2
- DST | c.19130G>A p.R6377H (on ENST00000361203 / NM_001374722.1; = p.R4074H on NM_015548.5) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs1224386090, COSV55040845; called by muse, mutect2
- FGF5 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 3/64 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV56889840; called by muse, mutect2
- GALNT12 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.119); catalogued as rs778487948, COSV100899172; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- GBP7 | c.358G>T p.V120L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.308); catalogued as COSV99643329; called by muse, mutect2, varscan2
- GRIA1 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs759117420, COSV53589188; called by muse, mutect2, varscan2
- GRIN2A | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as rs1567354612, COSV58029591; called by muse, mutect2, varscan2
- GUCA1A | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 71/190 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.86); catalogued as COSV50003691; called by muse, mutect2, varscan2
- HEATR1 | c.2686G>A p.V896M | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV100857730; called by muse, mutect2
- MYCBP2 | c.6433+2T>C p.X2145_splice (on ENST00000357337; = p.X2183_splice on NM_015057.5) | Splice Site (SNP) | VAF 3/38 reads (8%) | catalogued as COSV100631142; called by muse, mutect2
- PCDHB16 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as COSV53360342; called by muse, mutect2
- QSER1 | c.4828G>C p.E1610Q (on ENST00000399302; = p.E1739Q on NM_001076786.3) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.8); catalogued as COSV101234614; called by muse, mutect2, varscan2
- RYR3 | c.2001C>A p.D667E | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.902); catalogued as COSV101213395; called by muse, mutect2, varscan2
- SALL1 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057523061, COSV51758602; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SESN2 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53427960; called by muse, mutect2, varscan2
- TTC13 | c.1659G>A p.M553I | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100792970; called by muse, mutect2, varscan2
- USP22 | c.475A>T p.K159* | Nonsense Mutation (SNP) | VAF 55/146 reads (38%) | catalogued as COSV99820405; called by muse, mutect2, varscan2
- VARS1 | c.2762C>G p.A921G | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100791836; called by muse, mutect2, varscan2
- VPS13B | c.2267C>T p.P756L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1255400221, COSV100660858, COSV100662822; called by muse, mutect2, varscan2
- WDR48 | c.1181A>C p.K394T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100176784; called by mutect2, varscan2
- MAGEB6B | c.1151C>G p.P384R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PCOLCE | c.1242del p.E415Rfs*18 | Frame Shift Del (DEL) | VAF 26/85 reads (31%) | called by mutect2, pindel, varscan2
- CDC16 | c.1089G>A p.L363= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV99373056; called by muse, mutect2, varscan2
- DHX30 | c.1740G>A p.R580= (on ENST00000445061 / NM_138615.3; = p.R541= on NM_014966.3) | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- L3MBTL1 | c.2181G>A p.T727= (on ENST00000418998 / NM_001377303.1; = p.T637= on NM_015478.7) | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs778579008, COSV64228261; called by muse, mutect2, varscan2
- RENBP | c.513C>T p.D171= | Silent (SNP) | VAF 11/12 reads (92%) | catalogued as rs373960327, COSV100129555; called by muse, mutect2, varscan2
- SLC1A6 | c.888C>T p.F296= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs1251374481, COSV55667600; called by muse, varscan2
